Surgical pathology report (de-identified scan), TCGA case TCGA-LK-A4O0, project TCGA-MESO (Mesothelioma), tissue source site University of Pittsburgh, specimen TCGA-LK-A4O0-01A (Primary Tumor).

FINAL DIAGNOSIS:

PARTS 1

AND 2: BONES, 5TH AND 6TH RIBS, RESECTION -
SPECIMEN UNDERGOING DECALCIFICATION. ADDENDUM REPORT TO FOLLOW.

PART 3: PLEURA, LEFT, PLEURECTOMY -

DIFFUSE MALIGNANT MESOTHELIOMA, PREDOMINANTLY FIBROSARCOMATOUS TYPE, ARISING IN
ASSOCIATION WITH HYALINE PLEURAL PLAQUES AND ASSOCIATED WITH CHRONIC TALC PLEURITIS.

COMMENT:

The malignant mesothelioma is predominantly a fibrosarcomatous type although occasional areas of epithelioid differentiation are seen, particularly as the mesothelioma infiltrates adipose tissue. Immunostains show an immunophenotype that confirms the diagnosis of mesothelioma, in particular that the neoplastic cells express nuclear Calretinin and WT-1 and cytoplasmic D2-40 and CK5/6. Immunostains for Carcinoembryonic Antigen, B72.3, BER EP4, Leu-M1, and TTF-1 are negative. Histochemical stains for neutral mucin including PAS/PASD and Mucicarmine stains are negative.

ICD-O-3

Mesothelioma, NOS 9050/3

Site: pleura, NOS C38.4

hw
10/25/12

Source: NCI Genomic Data Commons file 5be63620-9ed1-4b56-bf91-4f79c3b99587 (TCGA-LK-A4O0.2BDA3DE7-2BBC-4D52-B5C7-AAD0043881AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).